Somatic mutation profile of tumor specimen ALCH-AD81-TTP1-A (aliquot ALCH-AD81-TTP1-A-2-0-D-A517-36) from ALCHEMIST case ALCH-AD81, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.7 years (26,538 days).
Specimen ALCH-AD81-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d61b1fbf-783e-42c5-a1e9-f738bf683244.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AD81-NB1-A (Blood Derived Normal), aliquot ALCH-AD81-NB1-A-1-0-D-A517-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/201837d6-8516-4445-b989-88c23f74a1f6

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 6, 5'UTR 2, Translation Start Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COBLL1 | c.1427C>T p.T476I (on ENST00000392717; = p.T438I on NM_014900.5) | Missense Mutation (SNP) | VAF 27/244 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.852); catalogued as rs1374558512; called by muse, mutect2
- KPTN | c.860A>G p.Y287C | Missense Mutation (SNP) | VAF 63/602 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1568454199; called by muse, mutect2
- PCDHGA1 | c.1735C>A p.P579T | Missense Mutation (SNP) | VAF 64/814 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65296123; called by muse, mutect2
- SPAG16 | c.1264G>T p.D422Y | Missense Mutation (SNP) | VAF 32/256 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs776705391, COSV59103890; called by muse, mutect2
- TAL1 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 29/337 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs1381701847; called by muse, mutect2
- ZNF17 | c.736T>C p.Y246H | Missense Mutation (SNP) | VAF 37/284 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.914); catalogued as rs763995393; called by muse, mutect2, varscan2
- ANKS3 | c.210G>A p.W70* | Nonsense Mutation (SNP) | VAF 60/908 reads (7%) | called by muse, mutect2
- CSNK1G3 | c.1078A>G p.K360E | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- DIS3L2 | c.830G>A p.R277K | Missense Mutation (SNP) | VAF 54/688 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.119); called by muse, mutect2
- H4-16 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 12/92 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); called by muse, varscan2
- MFSD4A | c.163T>A p.W55R | Missense Mutation (SNP) | VAF 64/690 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NLRP11 | c.1262G>A p.G421E | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PRKRA | c.473A>T p.E158V | Missense Mutation (SNP) | VAF 50/662 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RBM27 | c.1903A>G p.K635E | Missense Mutation (SNP) | VAF 12/181 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0.138); called by muse, mutect2
- RPF1 | c.917A>C p.Q306P | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- TBX3 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 32/398 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.478); called by muse, mutect2
- ADGRL3 | c.777C>T p.F259= (on ENST00000506720 / NM_001322402.2; = p.F191= on NM_015236.6) | Silent (SNP) | VAF 35/411 reads (9%) | called by muse, mutect2
- CMKLR1 | c.591A>T p.T197= (on ENST00000312143 / NM_001142344.2; = p.T195= on NM_004072.3) | Silent (SNP) | VAF 23/575 reads (4%) | called by muse, mutect2
- FRMPD3 | c.3420G>A p.A1140= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as rs371578570; called by muse, mutect2, varscan2
- KLHL5 | c.1236T>A p.P412= | Silent (SNP) | VAF 21/239 reads (9%) | catalogued as rs1161763571; called by muse, mutect2
- NDN | c.264G>A p.P88= | Silent (SNP) | VAF 34/347 reads (10%) | catalogued as COSV100086180; called by muse, mutect2
- PCDHGA8 | c.687C>T p.H229= | Silent (SNP) | VAF 59/511 reads (12%) | catalogued as rs747121608, COSV53930247; called by muse, mutect2, varscan2
- DBI | c.-35C>T | 5'UTR (SNP) | VAF 32/524 reads (6%) | catalogued as COSV100276027; called by muse, mutect2
- MMGT1 | c.-71C>T | 5'UTR (SNP) | VAF 21/518 reads (4%) | catalogued as rs909159652; called by muse, mutect2
